Gene-level copy-number profile of tumor specimen TCGA-V7-A7HQ-01A from TCGA case TCGA-V7-A7HQ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 75.8 years (27,684 days).
Specimen TCGA-V7-A7HQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.00d8d966-3b07-4ecc-aa3e-3adf967de41c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-V7-A7HQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/27eddc52-e3bc-4d7d-aa6b-6ed53e903da8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,366; copy number 2: 52,138; copy number 4: 1,522; copy number 5: 1,794.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-V7-A7HQ-01A-11D-A33D-01): tumor purity 0.75, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,794 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:22,440,819–28,238,905, 131 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr8:39,934,614–40,016,391, 2 genes, copy number 5 (within-gene range 1–5): IDO2, AC007991.1.
- chr8:40,114,651–145,066,685, 1,623 genes, copy number 5 (broad region; genes not listed).
- chr16:46,469,341–47,701,523, 38 genes, copy number 5 (within-gene range 1–5): ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2, DNAJA2, AC018845.3, AC018845.1, AC018845.2, NETO2, ITFG1-AS1, RPL23AP72, ITFG1, AC007494.2, AC007494.3, AC007494.1, AC007533.1, Y_RNA, 5S_rRNA, PHKB, RNA5SP425, AC007599.2, AC007599.1, EIF4BP5, NDUFA5P11.

Autosomal genes at a single copy (total copy number 1): 4,366. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
